Gene-level copy-number profile of tumor specimen TCGA-49-4505-01A from TCGA case TCGA-49-4505, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.0 years (22,628 days).
Specimen TCGA-49-4505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bb92211a-18dc-4733-b9de-92633aee2bae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4505-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d93bc0bb-8ad3-4e40-a587-bb9d09c6e18c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,313; copy number 2: 16,989; copy number 3: 23,067; copy number 4: 16,704; copy number 5: 1,038; copy number 6: 136; copy number 7: 81; copy number 8: 184; copy number 9: 25; copy number 11: 274.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4505-01A-01D-1204-01): tumor purity 0.45, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 564 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–30,743,704, 455 genes, copy number 8–11 (broad region; genes not listed).
- chr5:167,284,799–168,264,157, 1 gene, copy number 7 (within-gene range 2–7): TENM2.
- chr5:167,653,228–168,187,719, 7 genes, copy number 7 (within-gene range 5–7): AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2.
- chr5:169,263,601–169,604,778, 3 genes, copy number 8: MIR585, RNU6-477P, SPDL1.
- chr5:174,045,706–174,243,501, 1 gene, copy number 7 (within-gene range 3–7): NSG2.
- chr5:174,081,506–177,300,213, 72 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:181,114,106–181,342,213, 25 genes, copy number 9: AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.

Autosomal genes at a single copy (total copy number 1): 1,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
